Somatic mutation profile of cancer-model specimen HCM-SANG-0268-C18-85A (3D Organoid; aliquot HCM-SANG-0268-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0268-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0268-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1eed94d3-8b7b-4d43-9061-d45342767faa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0268-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0268-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac622459-86b6-466c-b6f8-24d17036a518

The open-access MAF lists 233 somatic variants for this specimen: 162 protein-altering or splice-affecting, 65 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 65, Nonsense Mutation 15, 5'Flank 3, In Frame Del 3, Frame Shift Del 3, Frame Shift Ins 3, Splice Region 2, Intron 2, Splice Site 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 54/107 reads (50%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 163/346 reads (47%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 459/678 reads (68%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 382/538 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 390/393 reads (99%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 192/307 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777711720, COSV99266809; called by muse, mutect2, varscan2
- ABCA6 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 191/192 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781051823, COSV52635635; called by muse, mutect2, varscan2
- AC092718.8 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 105/1398 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.127); catalogued as rs1199207705; called by muse, mutect2
- AC139530.2 | c.186dup p.K63Qfs*118 | Frame Shift Ins (INS) | VAF 340/652 reads (52%) | catalogued as rs769882870; called by mutect2, varscan2
- ANGPT4 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 587/1048 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV67921857; called by muse, mutect2, varscan2
- ANKRD11 | c.4067C>T p.S1356L | Missense Mutation (SNP) | VAF 140/657 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56376205; called by muse, mutect2, varscan2
- BARX2 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 584/925 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs370726265; called by muse, mutect2, varscan2
- BHMT2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs139123468; called by muse, mutect2, varscan2
- CARD11 | c.3418G>A p.G1140S | Missense Mutation (SNP) | VAF 466/731 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs373819371, COSV67798757; called by muse, mutect2, varscan2
- CCDC6 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 295/651 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs752730367; called by muse, mutect2, varscan2
- CD33 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 238/611 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs1312109365; called by muse, mutect2, varscan2
- CEP164 | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 187/551 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs200179277; called by muse, mutect2, varscan2
- CEP350 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 51/323 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100658280; called by muse, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 127/517 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CNGA3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 501/736 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs770308610, CM101949, COSV55623584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 774/777 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs781558600, COSV65669448; called by muse, mutect2, varscan2
- CSMD3 | c.9926A>T p.Y3309F (on ENST00000297405 / NM_001363185.1; = p.Y3140F on NM_052900.3) | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52142337; called by muse, mutect2, varscan2
- CUX1 | c.1616G>A p.R539H (on ENST00000437600 / NM_181500.4; = p.R541H on NM_001913.5) | Missense Mutation (SNP) | VAF 563/998 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs781850770, COSV52924878; called by muse, mutect2, varscan2
- DIRAS1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 280/950 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs746952074, COSV60216701; called by muse, mutect2, varscan2
- DMRTA1 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 32/976 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs1181553696; called by muse, mutect2
- DNAH11 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 688/1028 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1256071786; called by muse, varscan2
- DRD3 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.107); catalogued as rs768748323, COSV99879556, COSV99879648; called by muse, mutect2, varscan2
- ELMOD3 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs200965329, COSV55708168; called by muse, mutect2, varscan2
- EXT1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 92/383 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1006713733; called by muse, mutect2, varscan2
- F7 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 525/1229 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs888715728; called by muse, mutect2, varscan2
- FAT4 | c.7579G>A p.A2527T | Missense Mutation (SNP) | VAF 157/498 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs201007539, COSV58687043; called by muse, mutect2, varscan2
- FBXO33 | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53233270; called by mutect2, varscan2
- FZD9 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 834/1513 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329700001, COSV60669966; called by muse, mutect2, varscan2
- GALNT9 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 240/777 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1486896844; called by muse, mutect2, varscan2
- GGT7 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 133/1725 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs746629485; called by muse, mutect2
- GLI2 | c.3011G>A p.R1004H (on ENST00000361492 / NM_001374353.1; = p.R1021H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 846/1258 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs749819734, COSV58053376; called by muse, mutect2, varscan2
- GLS2 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 75/566 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs752169894, COSV57665746; called by muse, mutect2, varscan2
- GRIA2 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 413/678 reads (61%) | catalogued as COSV52388162; called by muse, mutect2, varscan2
- GSX1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 799/1770 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1451764232; called by muse, mutect2, varscan2
- HELZ2 | c.2603G>A p.R868Q (on ENST00000467148 / NM_001037335.2; = p.R299Q on NM_033405.3) | Missense Mutation (SNP) | VAF 305/1143 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs761392327; called by muse, mutect2, varscan2
- HERC2 | c.4522C>G p.P1508A | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1265963780; called by muse, mutect2, varscan2
- HGD | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 171/437 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM098246; called by muse, mutect2, varscan2
- HSPG2 | c.12007C>T p.R4003W | Missense Mutation (SNP) | VAF 245/518 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs529517544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL22 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 244/375 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs149366319; called by muse, mutect2, varscan2
- IREB2 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV99359434; called by muse, mutect2, varscan2
- ITGA10 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 234/236 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147724063; called by muse, varscan2
- ITGA2 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs746293859; called by muse, mutect2, varscan2
- ITPR1 | c.2339C>T p.A780V (on ENST00000354582; = p.A765V on NM_002222.7) | Missense Mutation (SNP) | VAF 190/759 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs781066658, COSV56974314; called by muse, mutect2, varscan2
- JCAD | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 39/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs190116152, COSV64761280; called by muse, mutect2
- JRK | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 95/848 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs376155400; called by muse, mutect2, varscan2
- KANSL1L | c.2315T>C p.I772T | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs865797914; called by muse, mutect2, varscan2
- KCNG2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 828/831 reads (100%) | catalogued as rs1234032328, COSV60267066; called by muse, mutect2, varscan2
- KCNK9 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 71/757 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs753123156, COSV57279105; called by muse, mutect2
- KRTAP25-1 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101342661; called by muse, mutect2, varscan2
- LIPE | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 276/901 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1568604638; called by muse, mutect2, varscan2
- LOXHD1 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 496/497 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs769584753, COSV56066863; called by muse, mutect2, varscan2
- LRCH4 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 504/1333 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs751406236; called by muse, mutect2, varscan2
- LRP1B | c.10294+1G>A p.X3432_splice | Splice Site (SNP) | VAF 58/182 reads (32%) | catalogued as COSV67207905; called by muse, varscan2
- LRRC17 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 84/614 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); catalogued as rs141714405; called by muse, mutect2, varscan2
- MAGEB6 | c.1025T>A p.V342E | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV66872470; called by muse, mutect2, varscan2
- MGMT | c.636G>C p.L212F (on ENST00000306010; = p.L181F on NM_002412.5) | Missense Mutation (SNP) | VAF 206/445 reads (46%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as rs200161468, COSV60027551; called by muse, mutect2, varscan2
- MUC12 | c.5174G>A p.R1725Q (on ENST00000379442; = p.R1582Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 536/3967 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.908); catalogued as rs775918699; called by muse, varscan2
- NKIRAS1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1031279337, COSV60667352; called by muse, mutect2, varscan2
- NPBWR1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 584/850 reads (69%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs776095073; called by muse, mutect2, varscan2
- OPRD1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 482/484 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs79344086; called by muse, mutect2, varscan2
- OR2AJ1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs895927038; called by mutect2, varscan2
- OR3A1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs765314124, COSV60163807; called by muse, mutect2, varscan2
- OR4F17 | c.248_249del p.K83Sfs*21 | Frame Shift Del (DEL) | VAF 97/578 reads (17%) | catalogued as rs758845698; called by mutect2, pindel, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 303/470 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- PALD1 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 168/353 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746010656, COSV54976421; called by muse, mutect2, varscan2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 513/784 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA11 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 306/657 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1315666503, COSV56520669; called by muse, mutect2, varscan2
- PCP4 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 120/258 reads (47%) | catalogued as rs144011084; called by muse, mutect2, varscan2
- PDHA2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 160/455 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs942723496, COSV54777147; called by muse, mutect2, varscan2
- PELI1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 151/489 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735093; called by muse, mutect2, varscan2
- PKD2L1 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 109/236 reads (46%) | catalogued as rs745318706, COSV58399353; called by muse, mutect2, varscan2
- PLCH2 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 161/164 reads (98%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.649); catalogued as rs1222164476; called by mutect2, varscan2
- PREX1 | c.3513C>T p.S1171= | Splice Region (SNP) | VAF 408/604 reads (68%) | catalogued as rs762648410, COSV64249827; called by muse, mutect2, varscan2
- PTX4 | c.1427G>A p.R476H (on ENST00000447419 / NM_001328608.2; = p.R471H on NM_001013658.1) | Missense Mutation (SNP) | VAF 226/309 reads (73%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs199861535; called by muse, mutect2, varscan2
- RAPGEF1 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 359/594 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1398777998; called by muse, mutect2, varscan2
- RBM4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 230/750 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.401); catalogued as rs750982375, COSV59519375; called by muse, mutect2, varscan2
- RBMS2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 39/378 reads (10%) | catalogued as rs138231675; called by muse, mutect2, varscan2
- ROBO1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs754068838, COSV71394290; called by muse, mutect2
- RPL5 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 237/240 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as rs778891633; called by muse, mutect2, varscan2
- RTN4 | c.2863G>A p.V955I | Missense Mutation (SNP) | VAF 282/444 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100463483; called by muse, mutect2, varscan2
- SACS | c.8864C>G p.T2955S | Missense Mutation (SNP) | VAF 157/576 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.609); catalogued as COSV66535549; called by muse, mutect2, varscan2
- SACS | c.7217C>G p.S2406C | Missense Mutation (SNP) | VAF 128/610 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV101207722; called by muse, mutect2, varscan2
- SHANK2 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 196/726 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53585131; called by muse, mutect2, varscan2
- SLC28A3 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 265/265 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); catalogued as rs747607766; called by muse, mutect2, varscan2
- SLC6A8 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 679/683 reads (99%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs372567920, CM154043, COSV99465871; called by muse, mutect2, varscan2
- SYN2 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 160/464 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372633861; called by muse, mutect2, varscan2
- SYPL2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 241/247 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200417619, COSV63995343; called by muse, mutect2, varscan2
- TAFA4 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 294/406 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs755227804, COSV55133917; called by muse, varscan2
- TSPAN11 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 87/844 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201664737, COSV53821531; called by muse, mutect2, varscan2
- USP10 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 207/492 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs760179345, COSV54752882; called by muse, mutect2, varscan2
- WNT10A | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 82/737 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs201178499; called by muse, mutect2, varscan2
- ZNF135 | c.1163G>A p.G388E (on ENST00000313434 / NM_001289401.2; = p.G400E on NM_003436.4) | Missense Mutation (SNP) | VAF 170/589 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs1280262565; called by muse, mutect2, varscan2
- AHNAK | c.12582dup p.K4195Qfs*22 | Frame Shift Ins (INS) | VAF 82/842 reads (10%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.2039A>G p.N680S | Missense Mutation (SNP) | VAF 219/309 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APEH | c.789_794del p.W263_H265delinsC | In Frame Del (DEL) | VAF 131/641 reads (20%) | called by mutect2, pindel*, varscan2*
- BRPF1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 139/630 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- BX276092.9 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CCDC88B | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 101/1039 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2
- CHDH | c.1258T>A p.Y420N | Missense Mutation (SNP) | VAF 83/442 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CNTNAP5 | c.2851G>T p.G951* | Nonsense Mutation (SNP) | VAF 163/513 reads (32%) | called by muse, mutect2, varscan2
- CWC22 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYP27A1 | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 207/610 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DENND3 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 93/682 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.2129G>C p.S710T | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EFCAB12 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 144/720 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH6B | c.1400_1402del p.K467del | In Frame Del (DEL) | VAF 174/360 reads (48%) | called by pindel, varscan2
- FAM160A1 | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 257/419 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FAM98A | c.805T>A p.L269M | Missense Mutation (SNP) | VAF 174/553 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FKBP1C | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 105/796 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FSTL5 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IREB2 | c.1950dup p.G651Rfs*3 | Frame Shift Ins (INS) | VAF 32/184 reads (17%) | called by mutect2, pindel, varscan2
- KIF15 | c.1685A>G p.K562R | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KIFC1 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 30/691 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHDC8A | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 584/590 reads (99%) | called by muse, varscan2
- KLRC1 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 50/510 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- LHFPL1 | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 322/326 reads (99%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LHX3 | c.479C>T p.P160L (on ENST00000371748 / NM_178138.6; = p.P165L on NM_014564.5) | Missense Mutation (SNP) | VAF 723/1064 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYPD2 | c.197del p.D66Afs*4 | Frame Shift Del (DEL) | VAF 63/536 reads (12%) | called by mutect2, pindel, varscan2
- MAGI2 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 70/448 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1A | c.7696C>T p.P2566S | Missense Mutation (SNP) | VAF 167/366 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- NAA16 | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 109/492 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NKTR | c.801A>C p.E267D | Missense Mutation (SNP) | VAF 218/324 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPIPB6 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 247/769 reads (32%) | called by muse, mutect2, varscan2
- OR2A5 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 59/843 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.052); called by muse, mutect2
- P2RY6 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 386/1190 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAK6 | c.1870T>G p.S624A | Missense Mutation (SNP) | VAF 161/336 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDHA2 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 154/468 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCD1 | c.1737C>G p.F579L | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PNMA8A | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 64/721 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- POTEJ | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 108/848 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- PREX2 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PTPRT | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 160/1224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM26 | c.2720_2722del p.L907del (on ENST00000438737 / NM_001366735.2; = p.L880del on NM_022118.5) | In Frame Del (DEL) | VAF 186/420 reads (44%) | called by pindel, varscan2
- RIPPLY2 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 68/1173 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- RNF13 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 204/264 reads (77%) | called by mutect2, varscan2
- RTN4RL2 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 299/954 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- SDAD1 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 138/438 reads (32%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2479C>A p.L827M | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SPINK9 | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 48/165 reads (29%) | called by mutect2, varscan2
- TADA3 | c.1108C>T p.L370= | Splice Region (SNP) | VAF 298/403 reads (74%) | called by muse, mutect2, varscan2
- TOLLIP | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- TRPC4 | c.894del p.E299Sfs*30 | Frame Shift Del (DEL) | VAF 84/358 reads (23%) | called by mutect2, pindel, varscan2
- TTC6 | c.1150A>C p.K384Q | Missense Mutation (SNP) | VAF 192/546 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- UTS2R | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 409/1298 reads (32%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- WDFY3 | c.3820G>C p.V1274L | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- WDR36 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 183/547 reads (33%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPO6 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 146/432 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.011); called by muse, varscan2
- YBX1 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- YRDC | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 290/291 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBED3 | c.88_99dup p.G30_P33dup | In Frame Ins (INS) | VAF 107/442 reads (24%) | called by mutect2, varscan2
- ZCCHC14 | c.1340A>C p.E447A (on ENST00000268616; = p.E584A on NM_015144.3) | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZDHHC13 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 68/234 reads (29%) | called by muse, mutect2, varscan2
- ZNF430 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 98/305 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ZNF440 | c.1357T>G p.S453A | Missense Mutation (SNP) | VAF 316/477 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF543 | c.1295T>A p.F432Y | Missense Mutation (SNP) | VAF 87/663 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF550 | c.1129G>T p.G377W | Missense Mutation (SNP) | VAF 200/556 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF837 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 625/970 reads (64%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD4 | c.1014C>T p.C338= | Silent (SNP) | VAF 138/429 reads (32%) | catalogued as rs374041322; called by muse, mutect2, varscan2
- ADAMTS3 | c.255G>A p.T85= | Silent (SNP) | VAF 169/626 reads (27%) | catalogued as COSV99710650; called by muse, mutect2, varscan2
- ANKRD55 | c.900G>A p.T300= | Silent (SNP) | VAF 201/404 reads (50%) | catalogued as rs770050070, COSV61950340; called by muse, mutect2, varscan2
- BCAT1 | c.1083G>C p.L361= | Silent (SNP) | VAF 129/565 reads (23%) | called by muse, mutect2, varscan2
- CDPF1 | c.147C>T p.P49= | Silent (SNP) | VAF 143/302 reads (47%) | catalogued as COSV53080760; called by muse, mutect2, varscan2
- CELSR1 | c.909C>T p.G303= | Silent (SNP) | VAF 348/714 reads (49%) | called by muse, mutect2, varscan2
- CFAP221 | c.1107C>T p.H369= | Silent (SNP) | VAF 124/351 reads (35%) | catalogued as rs752797632, COSV54654617; called by muse, mutect2, varscan2
- CHDH | c.1257T>A p.A419= | Silent (SNP) | VAF 85/446 reads (19%) | called by muse, mutect2, varscan2
- CLEC14A | c.1320G>A p.P440= | Silent (SNP) | VAF 150/518 reads (29%) | catalogued as rs1404808745; called by muse, mutect2, varscan2
- CPVL | c.498C>T p.H166= | Silent (SNP) | VAF 137/441 reads (31%) | catalogued as rs761586784, COSV99605617; called by muse, mutect2, varscan2
- CSDE1 | c.333C>T p.N111= | Silent (SNP) | VAF 360/364 reads (99%) | catalogued as rs1169324633; called by muse, mutect2, varscan2
- CSMD3 | c.3207A>T p.G1069= (on ENST00000297405 / NM_001363185.1; = p.G965= on NM_052900.3) | Silent (SNP) | VAF 116/306 reads (38%) | catalogued as COSV52187704; called by muse, mutect2, varscan2
- DAG1 | c.2529C>T p.N843= | Silent (SNP) | VAF 144/692 reads (21%) | called by muse, mutect2, varscan2
- DCDC1 | c.1635A>T p.P545= | Silent (SNP) | VAF 80/432 reads (19%) | called by muse, mutect2, varscan2
- DNMT1 | c.3996C>T p.H1332= | Silent (SNP) | VAF 293/833 reads (35%) | catalogued as rs751126457, COSV61576387; called by muse, mutect2, varscan2
- EHD3 | c.885C>T p.N295= | Silent (SNP) | VAF 146/436 reads (33%) | catalogued as rs199750636; called by muse, mutect2, varscan2
- EPHA5 | c.1812G>A p.G604= | Silent (SNP) | VAF 301/444 reads (68%) | called by muse, mutect2, varscan2
- FAR2 | c.384C>T p.N128= | Silent (SNP) | VAF 375/531 reads (71%) | catalogued as rs1565510933; called by muse, mutect2, varscan2
- FAT4 | c.9222A>G p.Q3074= | Silent (SNP) | VAF 63/458 reads (14%) | catalogued as rs541662297, COSV58704794; called by muse, mutect2, varscan2
- FBLL1 | c.453G>A p.P151= | Silent (SNP) | VAF 326/680 reads (48%) | called by muse, mutect2, varscan2
- FKBP1C | c.156C>A p.G52= | Silent (SNP) | VAF 108/796 reads (14%) | called by muse, mutect2, varscan2
- FOXP2 | c.1020C>T p.H340= | Silent (SNP) | VAF 107/500 reads (21%) | called by muse, mutect2, varscan2
- FOXRED2 | c.1095G>A p.P365= | Silent (SNP) | VAF 48/314 reads (15%) | catalogued as rs373269223; called by muse, varscan2
- GP5 | c.663G>A p.T221= | Silent (SNP) | VAF 138/674 reads (20%) | called by muse, mutect2, varscan2
- GPR151 | c.600G>A p.S200= | Silent (SNP) | VAF 133/274 reads (49%) | catalogued as rs1196250955, COSV57034992; called by muse, mutect2, varscan2
- GRPR | c.492C>A p.I164= | Silent (SNP) | VAF 26/430 reads (6%) | called by muse, mutect2
- HCK | c.615C>T p.N205= | Silent (SNP) | VAF 299/1129 reads (26%) | catalogued as rs986847689, COSV52940528; called by muse, mutect2, varscan2
- IGSF9B | c.3969G>A p.T1323= | Silent (SNP) | VAF 168/578 reads (29%) | catalogued as rs554567572; called by muse, mutect2, varscan2
- KIFC3 | c.1422C>T p.D474= | Silent (SNP) | VAF 293/698 reads (42%) | catalogued as rs1192762554; called by muse, varscan2
- LRP1 | c.6417C>T p.G2139= | Silent (SNP) | VAF 122/406 reads (30%) | catalogued as rs775810012; called by muse, varscan2
- LRRC37B | c.1770T>C p.Y590= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- MRS2 | c.1200A>G p.L400= | Silent (SNP) | VAF 238/239 reads (100%) | called by muse, mutect2, varscan2
- MS4A1 | c.246G>A p.V82= | Silent (SNP) | VAF 118/433 reads (27%) | called by muse, mutect2, varscan2
- MTBP | c.54G>T p.A18= | Silent (SNP) | VAF 162/423 reads (38%) | called by muse, mutect2, varscan2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 198/622 reads (32%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- NCAM1 | c.1401C>T p.N467= (on ENST00000316851 / NM_181351.5; = p.N457= on NM_000615.7) | Silent (SNP) | VAF 274/426 reads (64%) | called by muse, mutect2, varscan2
- NCKIPSD | c.1383C>T p.L461= | Silent (SNP) | VAF 175/680 reads (26%) | catalogued as rs1482290334, COSV53661212; called by muse, mutect2, varscan2
- NECAP1 | c.444G>A p.K148= | Silent (SNP) | VAF 119/528 reads (23%) | called by muse, mutect2, varscan2
- NGFR | c.864G>A p.R288= | Silent (SNP) | VAF 233/762 reads (31%) | called by muse, mutect2, varscan2
- NLRP2 | c.990C>T p.A330= | Silent (SNP) | VAF 280/885 reads (32%) | catalogued as rs375621121; called by muse, mutect2, varscan2
- NPTX2 | c.984C>T p.D328= | Silent (SNP) | VAF 525/1278 reads (41%) | catalogued as rs781445701, COSV55719214; called by muse, mutect2, varscan2
- NR2C2AP | c.138C>G p.S46= | Silent (SNP) | VAF 298/483 reads (62%) | called by muse, mutect2, varscan2
- ODF3L2 | c.151C>T p.L51= | Silent (SNP) | VAF 236/680 reads (35%) | called by muse, varscan2
- PCDH1 | c.2286T>C p.Y762= | Silent (SNP) | VAF 246/514 reads (48%) | catalogued as rs139365073; called by muse, mutect2
- PCDHA11 | c.1230C>T p.S410= | Silent (SNP) | VAF 47/457 reads (10%) | catalogued as rs564033882, COSV56532888; called by muse, mutect2, varscan2
- PCDHB6 | c.1473C>T p.P491= | Silent (SNP) | VAF 29/1020 reads (3%) | called by muse, mutect2
- PGLYRP1 | c.435C>T p.I145= | Silent (SNP) | VAF 362/569 reads (64%) | catalogued as COSV50517397; called by muse, mutect2, varscan2
- PORCN | c.666C>T p.N222= | Silent (SNP) | VAF 303/305 reads (99%) | catalogued as rs782299289, COSV58225941; called by muse, mutect2, varscan2
- PRKD1 | c.2277C>A p.G759= | Silent (SNP) | VAF 348/530 reads (66%) | called by muse, mutect2, varscan2
- PTRHD1 | c.168C>G p.T56= | Silent (SNP) | VAF 734/1138 reads (64%) | called by muse, mutect2, varscan2
- PXDN | c.2979C>T p.R993= | Silent (SNP) | VAF 295/884 reads (33%) | catalogued as rs933114521, COSV99411928; called by muse, mutect2, varscan2
- SNX10 | c.171C>T p.F57= | Silent (SNP) | VAF 299/487 reads (61%) | catalogued as rs192013192, COSV58400263; called by muse, mutect2, varscan2
- STXBP5L | c.3426A>C p.A1142= | Silent (SNP) | VAF 81/633 reads (13%) | called by muse, mutect2, varscan2
- TBCA | c.138A>G p.E46= | Silent (SNP) | VAF 65/136 reads (48%) | catalogued as COSV60538420; called by muse, mutect2, varscan2
- TBL1X | c.798C>T p.N266= | Silent (SNP) | VAF 76/317 reads (24%) | catalogued as rs763679092, COSV54276009; called by muse, mutect2, varscan2
- TCIRG1 | c.1548C>T p.I516= | Silent (SNP) | VAF 300/446 reads (67%) | catalogued as rs759410959, COSV55835632; called by muse, mutect2, varscan2
- TIMM50 | c.981C>T p.A327= | Silent (SNP) | VAF 351/583 reads (60%) | catalogued as rs375884282; called by muse, mutect2, varscan2
- TMEM185A | c.1038C>T p.I346= | Silent (SNP) | VAF 228/489 reads (47%) | catalogued as rs1478824799; called by muse, mutect2, varscan2
- TMPRSS15 | c.393G>T p.V131= | Silent (SNP) | VAF 107/207 reads (52%) | called by muse, mutect2, varscan2
- UTF1 | c.132C>T p.S44= | Silent (SNP) | VAF 304/620 reads (49%) | catalogued as rs1448621370; called by muse, mutect2, varscan2
- VCX3A | c.162G>T p.G54= | Silent (SNP) | VAF 24/131 reads (18%) | called by mutect2, varscan2
- WDR97 | c.4071G>A p.E1357= | Silent (SNP) | VAF 95/459 reads (21%) | called by muse, mutect2, varscan2
- WSCD1 | c.264G>T p.L88= | Silent (SNP) | VAF 378/770 reads (49%) | called by muse, mutect2, varscan2
- ZIK1 | c.27G>A p.P9= | Silent (SNP) | VAF 190/667 reads (28%) | catalogued as COSV56737262; called by muse, mutect2, varscan2
- ZMYM4 | c.915C>T p.G305= | Silent (SNP) | VAF 68/163 reads (42%) | called by muse, mutect2, varscan2
- CCNYL2 | chr10:42475880 C>T | 5'Flank (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
- FAM126A | c.992-1007G>A | Intron (SNP) | VAF 149/475 reads (31%) | catalogued as rs554419161, COSV69472327; called by muse, mutect2, varscan2
- FOXO1 | c.*92C>T | 3'UTR (SNP) | VAF 76/413 reads (18%) | called by muse, mutect2
- MIER1 | chr1:66926202 A>G | 5'Flank (SNP) | VAF 310/310 reads (100%) | catalogued as COSV62530444; called by muse, mutect2, varscan2
- WNK1 | c.2140-3169C>T | Intron (SNP) | VAF 98/1056 reads (9%) | catalogued as rs1485125173; called by muse, mutect2
- ZNF578 | chr19:52451360 C>T | 5'Flank (SNP) | VAF 165/798 reads (21%) | catalogued as rs763176135, COSV99990197; called by muse, mutect2, varscan2
